Somatic mutation profile of tumor specimen TARGET-10-PARXLS-09A (aliquot TARGET-10-PARXLS-09A-01D) from TARGET case TARGET-10-PARXLS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,601 days).
Specimen TARGET-10-PARXLS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd638b94-8248-4059-bbd6-e7253c9d6210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARXLS-14A (Bone Marrow Normal), aliquot TARGET-10-PARXLS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95557dc6-7165-4815-99e7-086e7e1375f3

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV51889357, COSV99336394; called by muse, mutect2, varscan2
- DNM2 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58971997; called by muse, mutect2, varscan2
- KRT74 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs555198932, COSV59773662; called by muse, mutect2, varscan2
- NOTCH1 | c.5126T>C p.L1709P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.765); catalogued as rs886043624, COSV53025282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDCD3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs145712203; called by muse, mutect2, varscan2
- PCDHB8 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs781814454, COSV50754565; called by muse, mutect2
- SLC7A13 | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV52537384; called by muse, mutect2, varscan2
- TECRL | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV67086444, COSV67089614; called by muse, mutect2, varscan2
- BCL11B | c.1351_1355delinsAGGGGCAGT p.G451Rfs*67 (on ENST00000357195 / NM_001282237.2; = p.G380Rfs*67 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/43 reads (51%) | called by pindel, varscan2*
- IGBP1 | c.496_498del p.K166del | In Frame Del (DEL) | VAF 48/56 reads (86%) | called by pindel, varscan2
- KANSL1 | c.2464_2491delinsCT p.V823Ffs*8 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | called by pindel, varscan2*
- OPRD1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- ZNF438 | c.1297_1298insTGTTCGGACCCGGA p.Y433Lfs*37 | Frame Shift Ins (INS) | VAF 40/88 reads (45%) | called by mutect2, pindel*, varscan2*
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506994 TGT>GAACCCCGGTGAG | Silent (INS) | VAF 33/95 reads (35%) | called by pindel, varscan2*
- LMX1B | c.462C>T p.D154= | Silent (SNP) | VAF 64/127 reads (50%) | catalogued as rs1389669108, COSV62742161; called by muse, mutect2, varscan2
- PDK2 | c.342C>T p.D114= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs565304713, COSV50303613; called by muse, mutect2, varscan2
- VGLL4 | c.177C>T p.S59= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- CPED1 | c.*23C>A | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MARCHF9 | c.514-103A>C | Intron (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+411C>G | Intron (SNP) | VAF 43/86 reads (50%) | catalogued as COSV53348806; called by muse, mutect2, varscan2
- TNNI3K | c.1773-17813C>A | Intron (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
